Somatic mutation profile of cancer-model specimen HCM-SANG-0266-C20-85A (3D Organoid; aliquot HCM-SANG-0266-C20-85A-01D-A79M-36), derived from the primary tumor of HCMI case HCM-SANG-0266-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; Tumor grade: G2.
Specimen HCM-SANG-0266-C20-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c9116022-ebb7-4a97-9b6b-39a4030d12f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0266-C20-10A (Blood Derived Normal), aliquot HCM-SANG-0266-C20-10A-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0163d956-f4c0-4c72-8687-157b8a28e020

The open-access MAF lists 259 somatic variants for this specimen: 195 protein-altering or splice-affecting, 53 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 167, Silent 53, Nonsense Mutation 10, Frame Shift Del 8, Intron 6, Splice Site 4, Frame Shift Ins 4, RNA 2, In Frame Del 2, 5'Flank 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.847C>T p.R283* | Nonsense Mutation (SNP) | VAF 85/85 reads (100%) | catalogued as rs786201856, CM920030, COSV57325157; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 156/258 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 162/250 reads (65%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- SACS | c.1640C>T p.P547L | Missense Mutation (SNP) | VAF 245/522 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as rs140507581; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AASS | c.9A>C p.Q3H | Missense Mutation (SNP) | VAF 52/210 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV62791379; called by muse, mutect2, varscan2
- ABHD12B | c.619G>A p.G207S (on ENST00000337334 / NM_001206673.2; = p.G130S on NM_181533.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 92/270 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as COSV100485861, COSV100485879; called by muse, mutect2, varscan2
- ACVR1C | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 131/484 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1267033436, COSV54648518; called by muse, mutect2, varscan2
- ADCY6 | c.1310C>T p.P437L | Missense Mutation (SNP) | VAF 14/482 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57168372; called by muse, mutect2
- ALDH1A2 | c.982G>A p.V328M | Missense Mutation (SNP) | VAF 274/274 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1230124736, COSV51080630; called by muse, mutect2, varscan2
- ANGPTL2 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 183/739 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1242036968; called by muse, mutect2, varscan2
- ARMCX1 | c.529A>G p.S177G | Missense Mutation (SNP) | VAF 119/744 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs782492899; called by muse, mutect2, varscan2
- ATP10A | c.2917G>A p.V973M | Missense Mutation (SNP) | VAF 303/304 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs763937984, COSV63521614; called by muse, mutect2, varscan2
- B2M | c.82C>T p.Q28* | Nonsense Mutation (SNP) | VAF 134/134 reads (100%) | catalogued as COSV62565489; called by muse, mutect2, varscan2
- COL5A2 | c.4055G>A p.S1352N | Missense Mutation (SNP) | VAF 238/464 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV66414863; called by muse, mutect2, varscan2
- CSMD1 | c.9421C>T p.R3141C (on ENST00000520002; = p.R3140C on NM_033225.6) | Missense Mutation (SNP) | VAF 212/435 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as rs543793837, COSV59370170; called by muse, varscan2
- CYP26B1 | c.980G>A p.R327Q | Missense Mutation (SNP) | VAF 403/786 reads (51%) | SIFT tolerated (0.48); PolyPhen benign (0.094); catalogued as rs200922951, COSV50011796; called by muse, mutect2, varscan2
- DCDC1 | c.2459T>G p.L820R | Missense Mutation (SNP) | VAF 92/273 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV60834171; called by muse, mutect2, varscan2
- DGKI | c.1698+1del p.X566_splice | Splice Site (DEL) | VAF 60/281 reads (21%) | catalogued as rs1563094809; called by mutect2, pindel, varscan2
- DGKI | c.520G>A p.V174M | Missense Mutation (SNP) | VAF 82/246 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as rs371221941; called by muse, mutect2, varscan2
- DNAH3 | c.8687G>A p.R2896H | Missense Mutation (SNP) | VAF 164/473 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748512714, COSV54519440; called by muse, mutect2, varscan2
- DNAH9 | c.7957G>T p.D2653Y | Missense Mutation (SNP) | VAF 95/475 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.244); catalogued as rs776546816, COSV52375013, COSV52381788; called by muse, mutect2, varscan2
- DNHD1 | c.13099del p.L4367Sfs*4 | Frame Shift Del (DEL) | VAF 74/350 reads (21%) | catalogued as COSV99601016; called by mutect2, pindel, varscan2
- EZHIP | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 481/1056 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.167); catalogued as rs994660093, COSV57955475; called by muse, mutect2, varscan2
- F8 | c.5169G>T p.E1723D | Missense Mutation (SNP) | VAF 272/549 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100811303; called by muse, mutect2, varscan2
- FAM13C | c.565G>A p.V189M | Missense Mutation (SNP) | VAF 126/411 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.12); catalogued as rs369435988; called by muse, mutect2, varscan2
- FAT3 | c.11990C>T p.P3997L | Missense Mutation (SNP) | VAF 105/400 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1305076760, COSV53070707; called by muse, mutect2, varscan2
- FCGR2A | c.734G>A p.R245Q (on ENST00000271450 / NM_001136219.3; = p.R244Q on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/252 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs746278098; called by muse, mutect2, varscan2
- GALNT7 | c.631G>A p.V211I | Missense Mutation (SNP) | VAF 74/252 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.196); catalogued as rs146899388; called by muse, varscan2
- GPR20 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 244/948 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as rs779977490, COSV66683999; called by muse, mutect2, varscan2
- GRHL1 | c.1822G>A p.G608R | Missense Mutation (SNP) | VAF 205/324 reads (63%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.538); catalogued as rs533437343, COSV61215974; called by muse, mutect2, varscan2
- GUCY1A2 | c.494A>C p.K165T | Missense Mutation (SNP) | VAF 15/209 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.084); catalogued as COSV104388945; called by muse, mutect2
- HNRNPUL1 | c.1697C>T p.T566M | Missense Mutation (SNP) | VAF 123/211 reads (58%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as rs754677243; called by muse, mutect2, varscan2
- HOOK2 | c.1057C>A p.R353S | Missense Mutation (SNP) | VAF 335/546 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs747052278; called by muse, mutect2, varscan2
- INHBA | c.347T>G p.L116R | Missense Mutation (SNP) | VAF 102/308 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0.091); catalogued as COSV54220904, COSV54224983; called by muse, varscan2
- ITLN2 | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 38/254 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs761824816; called by muse, mutect2, varscan2
- KANSL3 | c.1319+1G>A p.X440_splice | Splice Site (SNP) | VAF 71/334 reads (21%) | catalogued as COSV62623999; called by muse, mutect2, varscan2
- KIF2B | c.1816G>T p.G606W | Missense Mutation (SNP) | VAF 29/398 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.571); catalogued as rs752381198, COSV52131115, COSV99274886; called by muse, mutect2
- KXD1 | c.125A>G p.N42S | Missense Mutation (SNP) | VAF 126/372 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.751); catalogued as rs761708447; called by muse, mutect2, varscan2
- LRFN1 | c.1219G>A p.G407S | Missense Mutation (SNP) | VAF 153/477 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as rs1168390267, COSV50463142; called by muse, mutect2, varscan2
- LRRC4C | c.278T>G p.V93G | Missense Mutation (SNP) | VAF 130/524 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as rs954154310, COSV99540376; called by muse, mutect2
- MAGT1 | c.576G>T p.L192F (on ENST00000618282 / NM_001367916.1; = p.L224F on NM_032121.5) | Missense Mutation (SNP) | VAF 94/578 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as COSV100800459; called by muse, mutect2, varscan2
- MELK | c.976C>T p.R326W | Missense Mutation (SNP) | VAF 104/381 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs148081976, COSV53202385; called by muse, mutect2, varscan2
- MGA | c.7207C>G p.L2403V (on ENST00000219905 / NM_001164273.1; = p.L2194V on NM_001080541.2) | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV54948151; called by muse, mutect2, varscan2
- MVD | c.271C>T p.R91W | Missense Mutation (SNP) | VAF 229/347 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.699); catalogued as rs766800711; called by muse, mutect2, varscan2
- MYH7 | c.1849C>T p.L617F | Missense Mutation (SNP) | VAF 177/303 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as rs730880882; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NADSYN1 | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 55/232 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs369703615; called by muse, mutect2, varscan2
- NR2C1 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 56/212 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1179196240; called by muse, mutect2, varscan2
- OR2A1 | c.293C>T p.T98M | Missense Mutation (SNP) | VAF 141/515 reads (27%) | SIFT tolerated (0.75); PolyPhen benign (0.006); catalogued as rs750474119, COSV68822756; called by muse, mutect2, varscan2
- OR4A16 | c.87T>G p.F29L | Missense Mutation (SNP) | VAF 17/338 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.125); catalogued as COSV59043471; called by muse, mutect2
- OR4M1 | c.665T>C p.L222P | Missense Mutation (SNP) | VAF 94/1290 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs148618328; called by muse, mutect2
- OR8K3 | c.23C>T p.T8M | Missense Mutation (SNP) | VAF 99/351 reads (28%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as rs766060464, COSV57130713, COSV57130774; called by muse, mutect2, varscan2
- PCDH10 | c.911C>T p.S304L | Missense Mutation (SNP) | VAF 163/537 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as rs756259780; called by muse, varscan2
- PCDHB2 | c.2102C>T p.S701L | Missense Mutation (SNP) | VAF 273/803 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.052); catalogued as COSV99165209; called by muse, mutect2, varscan2
- PDGFRA | c.248C>T p.T83M | Missense Mutation (SNP) | VAF 123/396 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs779332376, COSV57271921; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDGFRA | c.3040G>A p.A1014T | Missense Mutation (SNP) | VAF 277/432 reads (64%) | SIFT tolerated (0.26); PolyPhen benign (0.054); catalogued as rs768291477, COSV57276941; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEC | c.4658G>A p.R1553H (on ENST00000322810 / NM_201380.4; = p.R1443H on NM_000445.5) | Missense Mutation (SNP) | VAF 468/976 reads (48%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs565291398; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POTEH | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 443/770 reads (58%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.555); catalogued as rs760807244, COSV58882143; called by muse, mutect2, varscan2
- PRICKLE2 | c.1475G>A p.G492E (on ENST00000295902; = p.G436E on NM_198859.4) | Missense Mutation (SNP) | VAF 287/447 reads (64%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.543); catalogued as rs140007626, COSV55767482; called by muse, mutect2, varscan2
- RDX | c.1564G>C p.E522Q | Missense Mutation (SNP) | VAF 196/305 reads (64%) | SIFT tolerated (0.26); PolyPhen benign (0.054); catalogued as COSV100563121; called by muse, mutect2
- RERE | c.907C>A p.P303T | Missense Mutation (SNP) | VAF 48/165 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV61938813; called by muse, mutect2, varscan2
- SLC28A2 | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 100/256 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as COSV61664987; called by muse, mutect2, varscan2
- SLC30A3 | c.244G>A p.V82I | Missense Mutation (SNP) | VAF 205/430 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.131); catalogued as rs749270034, COSV51986908; called by muse, varscan2
- SLC36A1 | c.1216G>A p.V406M | Missense Mutation (SNP) | VAF 155/509 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.473); catalogued as rs569783367; called by muse, mutect2, varscan2
- SLC4A3 | c.2986G>A p.V996I | Missense Mutation (SNP) | VAF 208/446 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs553370981, COSV56091201; called by muse, varscan2
- SLC6A20 | c.563G>T p.G188V | Missense Mutation (SNP) | VAF 209/359 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760631089, COSV62072939; called by muse, mutect2, varscan2
- SLITRK6 | c.263C>A p.T88N | Missense Mutation (SNP) | VAF 132/524 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV68390394; called by muse, mutect2, varscan2
- SMAD4 | c.1496G>A p.C499Y | Missense Mutation (SNP) | VAF 265/265 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV61690085; called by muse, mutect2, varscan2
- STAG2 | c.2409G>A p.M803I | Missense Mutation (SNP) | VAF 248/493 reads (50%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV54360934; called by muse, mutect2, varscan2
- TCF7L2 | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 123/479 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); catalogued as COSV60513598; called by muse, mutect2, varscan2
- TET3 | c.1633G>A p.D545N | Missense Mutation (SNP) | VAF 323/668 reads (48%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as rs773379637; called by muse, varscan2
- TMEM81 | c.718G>A p.V240M | Missense Mutation (SNP) | VAF 116/386 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.11); catalogued as rs759785457, COSV52702763; called by muse, mutect2, varscan2
- TMX4 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 65/426 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772374070, COSV99851701; called by muse, mutect2, varscan2
- TPO | c.565C>T p.R189* | Nonsense Mutation (SNP) | VAF 291/639 reads (46%) | catalogued as rs957075099, COSV100219881; called by muse, mutect2, varscan2
- TRPV6 | c.1513G>A p.V505I | Missense Mutation (SNP) | VAF 198/603 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.314); catalogued as rs369658985; called by muse, mutect2, varscan2
- WDR7 | c.598-1G>T p.X200_splice | Splice Site (SNP) | VAF 85/138 reads (62%) | catalogued as COSV99588518; called by muse, mutect2, varscan2
- ZCCHC3 | c.32G>A p.R11K | Missense Mutation (SNP) | VAF 399/793 reads (50%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs1460743094; called by muse, mutect2, varscan2
- ZDHHC15 | c.79G>A p.V27I | Missense Mutation (SNP) | VAF 291/587 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100973584; called by muse, mutect2, varscan2
- ZNF283 | c.1757T>C p.L586P | Missense Mutation (SNP) | VAF 116/384 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1458333816; called by muse, mutect2, varscan2
- ZNF626 | c.1499A>G p.E500G | Missense Mutation (SNP) | VAF 56/270 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs1405480375, COSV74129073; called by muse, mutect2, varscan2
- ACO1 | c.1137A>C p.K379N | Missense Mutation (SNP) | VAF 79/524 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ANK2 | c.11206T>G p.S3736A | Missense Mutation (SNP) | VAF 107/326 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- ANKRD30A | c.1087A>T p.S363C (on ENST00000611781; = p.S307C on NM_052997.2) | Missense Mutation (SNP) | VAF 102/435 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- ARHGAP24 | c.1376C>A p.A459D (on ENST00000395184 / NM_001025616.3; = p.A366D on NM_031305.3) | Missense Mutation (SNP) | VAF 93/348 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- ARHGAP32 | c.2763A>C p.E921D (on ENST00000310343 / NM_001378025.1; = p.E572D on NM_014715.4) | Missense Mutation (SNP) | VAF 155/401 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ARHGAP4 | c.1311_1322del p.E437_L441delinsD | In Frame Del (DEL) | VAF 89/604 reads (15%) | called by mutect2, pindel, varscan2
- ATP1A4 | c.513C>A p.N171K | Missense Mutation (SNP) | VAF 60/239 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- BCAR1 | c.409T>A p.F137I | Missense Mutation (SNP) | VAF 123/514 reads (24%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- C19orf33 | c.259A>G p.K87E | Missense Mutation (SNP) | VAF 172/274 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); called by mutect2, varscan2
- C1orf68 | c.367A>C p.S123R | Missense Mutation (SNP) | VAF 149/541 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- CACNB2 | c.1048A>C p.S350R (on ENST00000324631 / NM_201596.3; = p.S295R on NM_000724.4) | Missense Mutation (SNP) | VAF 47/215 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- CAPN6 | c.1634G>A p.C545Y | Missense Mutation (SNP) | VAF 178/381 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CCDC173 | c.1106A>G p.K369R | Missense Mutation (SNP) | VAF 207/449 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- CELSR1 | c.4063T>G p.F1355V | Missense Mutation (SNP) | VAF 175/536 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- CEP57 | c.1372G>A p.G458R | Missense Mutation (SNP) | VAF 195/273 reads (71%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CFAP46 | c.6613+1G>A p.X2205_splice | Splice Site (SNP) | VAF 30/406 reads (7%) | called by muse, mutect2
- CFAP54 | c.8942G>T p.W2981L | Missense Mutation (SNP) | VAF 75/230 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- CFAP69 | c.335A>T p.Y112F | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- CLCNKB | c.1678A>T p.K560* | Nonsense Mutation (SNP) | VAF 40/315 reads (13%) | called by muse, mutect2
- CLDN8 | c.546C>A p.F182L | Missense Mutation (SNP) | VAF 209/318 reads (66%) | SIFT tolerated (0.65); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- COL3A1 | c.687A>C p.K229N | Missense Mutation (SNP) | VAF 16/367 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.388); called by muse, mutect2
- COL6A5 | c.7406T>G p.L2469R (on ENST00000312481; = p.L2465R on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 106/382 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CORIN | c.1948A>T p.K650* | Nonsense Mutation (SNP) | VAF 62/254 reads (24%) | called by muse, mutect2, varscan2
- CSMD1 | c.817T>A p.W273R | Missense Mutation (SNP) | VAF 10/300 reads (3%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2
- DMD | c.1196T>C p.I399T | Missense Mutation (SNP) | VAF 292/610 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- DNHD1 | c.8252C>A p.P2751Q | Missense Mutation (SNP) | VAF 131/431 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- DPP3 | c.417A>C p.E139D | Missense Mutation (SNP) | VAF 71/389 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1415C>G p.S472C | Missense Mutation (SNP) | VAF 181/276 reads (66%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- ELFN2 | c.909C>A p.H303Q | Missense Mutation (SNP) | VAF 126/563 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ELOVL5 | c.814G>A p.G272R | Missense Mutation (SNP) | VAF 267/390 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- EPS8L3 | c.1336C>T p.P446S (on ENST00000361965 / NM_133181.4; = p.P416S on NM_024526.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 314/486 reads (65%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EVX1 | c.635_639del p.R212Lfs*2 | Frame Shift Del (DEL) | VAF 77/388 reads (20%) | called by mutect2, pindel, varscan2
- FER1L5 | c.806T>G p.V269G (on ENST00000623019; = p.V286G on NM_001293083.2) | Missense Mutation (SNP) | VAF 234/507 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FSIP2 | c.5932T>A p.C1978S | Missense Mutation (SNP) | VAF 26/420 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0.3); called by muse, mutect2
- GRIA4 | c.1922A>C p.N641T | Missense Mutation (SNP) | VAF 124/367 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HACL1 | c.1336G>A p.G446R | Missense Mutation (SNP) | VAF 146/426 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- HERC2 | c.2873A>T p.D958V | Missense Mutation (SNP) | VAF 86/192 reads (45%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- HERC2 | c.2872G>T p.D958Y | Missense Mutation (SNP) | VAF 84/190 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IFNA17 | c.321_322insC p.F108Lfs*4 | Frame Shift Ins (INS) | VAF 92/531 reads (17%) | called by mutect2, varscan2
- IGFLR1 | c.763G>A p.D255N | Missense Mutation (SNP) | VAF 43/383 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- IL1RL2 | c.1613C>A p.P538H | Missense Mutation (SNP) | VAF 134/585 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- INTS6L | c.277A>T p.R93* | Nonsense Mutation (SNP) | VAF 89/539 reads (17%) | called by muse, mutect2, varscan2
- ITGA8 | c.2055A>C p.E685D | Missense Mutation (SNP) | VAF 109/388 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITGAD | c.3008_3013del p.S1003_D1004del | In Frame Del (DEL) | VAF 71/316 reads (22%) | called by mutect2, pindel, varscan2
- KANSL3 | c.1319G>C p.R440T | Missense Mutation (SNP) | VAF 72/341 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KCTD8 | c.366G>C p.E122D | Missense Mutation (SNP) | VAF 22/512 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.028); called by muse, mutect2
- KIZ | c.1650A>T p.E550D | Missense Mutation (SNP) | VAF 21/314 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.119); called by muse, mutect2
- LRFN1 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 313/465 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAGEB16 | c.493A>G p.I165V | Missense Mutation (SNP) | VAF 208/836 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MAP3K7CL | c.329A>C p.K110T | Missense Mutation (SNP) | VAF 119/389 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MARCHF11 | c.88C>A p.P30T | Missense Mutation (SNP) | VAF 16/304 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.641); called by muse, mutect2
- MCM7 | c.2109G>T p.E703D | Missense Mutation (SNP) | VAF 34/436 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.014); called by muse, mutect2
- MIA2 | c.374C>T p.T125I | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MMRN2 | c.739A>G p.S247G | Missense Mutation (SNP) | VAF 110/349 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MROH5 | c.1699G>T p.D567Y | Missense Mutation (SNP) | VAF 214/456 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- MRPL15 | c.694G>C p.A232P | Missense Mutation (SNP) | VAF 93/535 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- MUC16 | c.33735A>C p.E11245D | Missense Mutation (SNP) | VAF 81/342 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- NAV1 | c.4727_4731del p.V1576Afs*5 | Frame Shift Del (DEL) | VAF 46/551 reads (8%) | called by mutect2, pindel
- NCOA5 | c.318G>A p.M106I | Missense Mutation (SNP) | VAF 247/505 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- NCOR1 | c.4284A>T p.K1428N | Missense Mutation (SNP) | VAF 110/342 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NCR1 | c.460T>A p.L154I | Missense Mutation (SNP) | VAF 252/720 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- NFIB | c.30G>C p.Q10H | Missense Mutation (SNP) | VAF 98/484 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- NKAIN3 | c.113T>G p.L38R | Missense Mutation (SNP) | VAF 98/478 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NKAPL | c.738dup p.E247Rfs*4 | Frame Shift Ins (INS) | VAF 79/306 reads (26%) | called by mutect2, pindel, varscan2
- OPRK1 | c.194T>C p.V65A | Missense Mutation (SNP) | VAF 158/610 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- OPRL1 | c.96_99del p.P33Rfs*49 | Frame Shift Del (DEL) | VAF 157/895 reads (18%) | called by mutect2, pindel, varscan2
- OR2AJ1 | c.278C>A p.S93* | Nonsense Mutation (SNP) | VAF 106/399 reads (27%) | called by muse, mutect2, varscan2
- OR2B2 | c.287G>C p.G96A | Missense Mutation (SNP) | VAF 73/324 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); called by muse, mutect2, varscan2
- OR2I1P | c.761C>T p.S254L | Missense Mutation (SNP) | VAF 166/520 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- PCDHA10 | c.2178_2190del p.E727Gfs*3 | Frame Shift Del (DEL) | VAF 117/497 reads (24%) | called by mutect2, pindel, varscan2
- PDCD11 | c.3065C>T p.A1022V | Missense Mutation (SNP) | VAF 154/473 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PHLDB2 | c.1648_1654del p.T550Hfs*17 | Frame Shift Del (DEL) | VAF 73/395 reads (18%) | called by mutect2, pindel, varscan2
- PIWIL4 | c.2135dup p.S713Efs*51 | Frame Shift Ins (INS) | VAF 30/306 reads (10%) | called by mutect2, pindel, varscan2
- PKNOX2 | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 119/390 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PLEKHG1 | c.1540C>T p.P514S | Missense Mutation (SNP) | VAF 89/260 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- POLR1E | c.1104C>G p.I368M (on ENST00000377792 / NM_001282766.1; = p.I306M on NM_022490.4) | Missense Mutation (SNP) | VAF 53/370 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PPM1E | c.1913A>C p.Q638P | Missense Mutation (SNP) | VAF 99/321 reads (31%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- PRKAB2 | c.451A>G p.N151D | Missense Mutation (SNP) | VAF 97/308 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- RAD54B | c.515del p.F172Sfs*13 | Frame Shift Del (DEL) | VAF 40/269 reads (15%) | called by mutect2, pindel, varscan2
- RBL2 | c.512_525del p.Q171Lfs*24 | Frame Shift Del (DEL) | VAF 32/217 reads (15%) | called by mutect2, pindel, varscan2
- RCOR1 | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 67/200 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- RERE | c.908C>T p.P303L | Missense Mutation (SNP) | VAF 49/167 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RNF111 | c.972dup p.E325* | Frame Shift Ins (INS) | VAF 155/219 reads (71%) | called by mutect2, pindel, varscan2
- RNF181 | c.88T>C p.S30P | Missense Mutation (SNP) | VAF 155/326 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- RP1 | c.3482G>A p.G1161E | Missense Mutation (SNP) | VAF 63/337 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SAMD9L | c.3442G>T p.D1148Y | Missense Mutation (SNP) | VAF 125/352 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- SAMD9L | c.992A>C p.K331T | Missense Mutation (SNP) | VAF 77/251 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SCAF4 | c.3326T>G p.L1109R | Missense Mutation (SNP) | VAF 147/504 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SGMS2 | c.419G>T p.G140V | Missense Mutation (SNP) | VAF 121/222 reads (55%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SHANK2 | c.2377A>G p.R793G | Missense Mutation (SNP) | VAF 311/511 reads (61%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- SLC6A20 | c.562G>T p.G188C | Missense Mutation (SNP) | VAF 210/360 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLIT2 | c.95G>A p.C32Y | Missense Mutation (SNP) | VAF 237/675 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SORBS1 | c.2477T>C p.I826T (on ENST00000361941 / NM_001034954.2; = p.I476T on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 234/360 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- SOX1 | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 128/901 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); called by muse, varscan2
- SP2 | c.1486C>T p.P496S | Missense Mutation (SNP) | VAF 47/440 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TAF11L14 | c.235C>T p.Q79* | Nonsense Mutation (SNP) | VAF 92/322 reads (29%) | called by muse, mutect2, varscan2
- TAF7L | c.320C>G p.P107R | Missense Mutation (SNP) | VAF 34/454 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TBK1 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 224/337 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TGFBRAP1 | c.1223C>G p.A408G | Missense Mutation (SNP) | VAF 150/540 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- TIGIT | c.118T>A p.S40T | Missense Mutation (SNP) | VAF 105/297 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- TMEM151A | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 426/687 reads (62%) | SIFT tolerated (0.05); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- TRBV27 | c.126T>G p.C42W | Missense Mutation (SNP) | VAF 36/353 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTC21B | c.2689C>T p.Q897* | Nonsense Mutation (SNP) | VAF 246/394 reads (62%) | called by muse, mutect2, varscan2
- TTN | c.19498A>C p.S6500R (on ENST00000591111; = p.S5573R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/506 reads (16%) | PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- TTN | c.5983G>T p.E1995* (on ENST00000591111; = p.E1949* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 267/596 reads (45%) | called by muse, mutect2, varscan2
- TXLNA | c.1394A>C p.Q465P | Missense Mutation (SNP) | VAF 227/349 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- UBE2T | c.452C>G p.A151G | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); called by muse, mutect2
- UGT1A4 | c.194T>C p.V65A | Missense Mutation (SNP) | VAF 266/571 reads (47%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- USP22 | c.1483G>A p.D495N | Missense Mutation (SNP) | VAF 248/382 reads (65%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.85); called by muse, varscan2
- VGLL3 | c.254A>C p.N85T | Missense Mutation (SNP) | VAF 54/554 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); called by muse, mutect2
- VIPAS39 | c.93G>T p.Q31H | Missense Mutation (SNP) | VAF 62/223 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); called by muse, varscan2
- VPS13C | c.2090C>G p.S697C (on ENST00000644861 / NM_020821.3; = p.S654C on NM_017684.5) | Missense Mutation (SNP) | VAF 144/144 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- XIRP2 | c.4337G>C p.R1446T (on ENST00000628543; = p.R1621T on NM_152381.6) | Missense Mutation (SNP) | VAF 67/263 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- XIRP2 | c.4790A>C p.K1597T (on ENST00000628543; = p.K1772T on NM_152381.6) | Missense Mutation (SNP) | VAF 95/392 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ZNF559 | c.650A>G p.E217G | Missense Mutation (SNP) | VAF 20/300 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.412); called by muse, mutect2
- ZNF680 | c.224A>C p.K75T | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2
- ARX | c.420C>T p.D140= | Silent (SNP) | VAF 85/261 reads (33%) | called by muse, mutect2, varscan2
- ASB6 | c.684C>T p.D228= | Silent (SNP) | VAF 172/630 reads (27%) | called by muse, mutect2, varscan2
- CAB39 | c.252A>C p.V84= | Silent (SNP) | VAF 30/424 reads (7%) | called by muse, mutect2
- CADPS2 | c.1233T>C p.T411= | Silent (SNP) | VAF 55/236 reads (23%) | called by muse, mutect2, varscan2
- CD1A | c.954G>A p.A318= | Silent (SNP) | VAF 180/308 reads (58%) | catalogued as rs768867270, COSV56861045; called by muse, mutect2, varscan2
- CD34 | c.903G>A p.L301= | Silent (SNP) | VAF 208/319 reads (65%) | called by muse, mutect2, varscan2
- CSPG4 | c.2091G>A p.V697= | Silent (SNP) | VAF 337/339 reads (99%) | called by muse, mutect2, varscan2
- DHPS | c.480G>A p.E160= | Silent (SNP) | VAF 18/290 reads (6%) | called by muse, mutect2
- DHX37 | c.1569G>A p.R523= | Silent (SNP) | VAF 232/348 reads (67%) | called by muse, mutect2, varscan2
- DSEL | c.2958C>T p.G986= | Silent (SNP) | VAF 301/301 reads (100%) | catalogued as rs200130664, COSV59489603; called by muse, mutect2, varscan2
- EEF1AKNMT | c.909C>T p.F303= (on ENST00000361735 / NM_015935.5; = p.F217= on NM_014955.3) | Silent (SNP) | VAF 143/223 reads (64%) | catalogued as rs1390126080, COSV62283443; called by muse, mutect2, varscan2
- EPHB3 | c.837C>A p.A279= | Silent (SNP) | VAF 119/370 reads (32%) | called by muse, mutect2, varscan2
- ESCO2 | c.289C>T p.L97= | Silent (SNP) | VAF 24/414 reads (6%) | called by muse, mutect2
- FBLN2 | c.1473C>T p.A491= | Silent (SNP) | VAF 235/364 reads (65%) | catalogued as rs775767006; called by muse, mutect2, varscan2
- GHSR | c.390G>A p.T130= | Silent (SNP) | VAF 311/471 reads (66%) | catalogued as rs1038994905; called by muse, mutect2, varscan2
- GNL1 | c.753C>T p.V251= | Silent (SNP) | VAF 145/414 reads (35%) | catalogued as rs373106261; called by muse, mutect2
- HCRTR1 | c.696C>G p.A232= | Silent (SNP) | VAF 46/551 reads (8%) | called by muse, mutect2
- HLX | c.1089C>T p.D363= | Silent (SNP) | VAF 158/560 reads (28%) | catalogued as rs750390120; called by muse, mutect2, varscan2
- KHDC1 | c.633C>T p.T211= (on ENST00000370384 / NM_001251874.2; = p.T138= on NM_030568.5) | Silent (SNP) | VAF 108/285 reads (38%) | catalogued as rs190629651; called by muse, mutect2, varscan2
- KMT5A | c.966C>T p.A322= | Silent (SNP) | VAF 151/436 reads (35%) | called by muse, mutect2, varscan2
- LACC1 | c.1041G>A p.R347= | Silent (SNP) | VAF 91/477 reads (19%) | called by muse, mutect2, varscan2
- LCAT | c.1186C>T p.L396= | Silent (SNP) | VAF 149/452 reads (33%) | called by muse, mutect2, varscan2
- MAGEB5 | c.289T>C p.L97= | Silent (SNP) | VAF 159/630 reads (25%) | catalogued as COSV66868829; called by muse, mutect2, varscan2
- MLLT1 | c.163C>T p.L55= | Silent (SNP) | VAF 55/389 reads (14%) | called by muse, mutect2, varscan2
- NBPF11 | c.861C>T p.N287= | Silent (SNP) | VAF 136/260 reads (52%) | called by muse, mutect2, varscan2
- NEK11 | c.696C>T p.F232= | Silent (SNP) | VAF 66/389 reads (17%) | catalogued as rs759501857; called by muse, mutect2, varscan2
- NFASC | c.1302G>A p.S434= (on ENST00000339876 / NM_001378329.1; = p.S445= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 96/273 reads (35%) | catalogued as rs750856686, COSV58361811; called by muse, mutect2, varscan2
- NPAS1 | c.1062C>T p.H354= | Silent (SNP) | VAF 26/439 reads (6%) | called by muse, mutect2
- OR56A4 | c.624C>G p.A208= | Silent (SNP) | VAF 219/335 reads (65%) | catalogued as COSV58109709; called by muse, mutect2, varscan2
- PRODH2 | c.948G>A p.E316= (on ENST00000301175; = p.E240= on NM_021232.2 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 223/390 reads (57%) | called by muse, mutect2, varscan2
- PTPRQ | c.6759A>T p.I2253= (on ENST00000616559; = p.I2220= on NM_001145026.2) | Silent (SNP) | VAF 80/265 reads (30%) | called by muse, mutect2, varscan2
- RAI1 | c.1137C>T p.T379= | Silent (SNP) | VAF 367/573 reads (64%) | catalogued as rs780860899; called by muse, mutect2, varscan2
- RBL1 | c.1698A>G p.L566= | Silent (SNP) | VAF 275/560 reads (49%) | called by muse, mutect2, varscan2
- RGMA | c.384G>A p.T128= | Silent (SNP) | VAF 375/379 reads (99%) | catalogued as rs1171718224; called by muse, mutect2, varscan2
- RIMS2 | c.786G>A p.S262= (on ENST00000666250 / NM_001348490.2; = p.S70= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 186/373 reads (50%) | catalogued as COSV51699757; called by muse, mutect2, varscan2
- RIMS2 | c.2922C>T p.T974= (on ENST00000666250 / NM_001348490.2; = p.T782= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 76/338 reads (22%) | catalogued as rs765015367, COSV51671152; called by muse, mutect2, varscan2
- RYR1 | c.8244G>A p.P2748= | Silent (SNP) | VAF 105/305 reads (34%) | catalogued as rs749048565, COSV100614756; called by muse, mutect2, varscan2
- SBF1 | c.1395T>A p.R465= | Silent (SNP) | VAF 120/377 reads (32%) | catalogued as rs1198709874, COSV62367442; called by muse, mutect2, varscan2
- SCARF2 | c.2229G>A p.P743= | Silent (SNP) | VAF 374/576 reads (65%) | called by muse, mutect2, varscan2
- SCRT1 | c.435C>T p.P145= | Silent (SNP) | VAF 286/556 reads (51%) | called by muse, mutect2, varscan2
- SH2D1A | c.102C>T p.S34= | Silent (SNP) | VAF 121/493 reads (25%) | catalogued as rs1484311033, CM1010330, COSV63579003; called by muse, mutect2, varscan2
- SMARCAD1 | c.72C>T p.T24= | Silent (SNP) | VAF 133/403 reads (33%) | called by muse, mutect2, varscan2
- STK19 | c.108C>T p.T36= | Silent (SNP) | VAF 228/776 reads (29%) | catalogued as rs200175775; called by muse, mutect2, varscan2
- TBXT | c.345G>A p.P115= | Silent (SNP) | VAF 197/639 reads (31%) | called by muse, mutect2, varscan2
- TCL1B | c.9C>T p.S3= | Silent (SNP) | VAF 84/279 reads (30%) | catalogued as rs1053432353; called by muse, mutect2, varscan2
- TTN | c.82185G>A p.K27395= (on ENST00000591111; = p.K19971= on NM_003319.4) | Silent (SNP) | VAF 144/356 reads (40%) | catalogued as rs1376529658; called by muse, mutect2
- TTN | c.5982G>T p.S1994= (on ENST00000591111; = p.S1948= on NM_003319.4) | Silent (SNP) | VAF 268/593 reads (45%) | catalogued as COSV59887364; called by muse, mutect2, varscan2
- VEGFC | c.579T>G p.S193= | Silent (SNP) | VAF 24/339 reads (7%) | catalogued as COSV54599701; called by muse, mutect2
- XAF1 | c.141G>A p.E47= | Silent (SNP) | VAF 103/338 reads (30%) | called by muse, mutect2, varscan2
- ZNF329 | c.1521G>A p.R507= | Silent (SNP) | VAF 146/461 reads (32%) | catalogued as rs1304377638, COSV100798740; called by muse, mutect2, varscan2
- ZNF462 | c.4833G>A p.S1611= | Silent (SNP) | VAF 491/661 reads (74%) | catalogued as rs144602357; called by muse, mutect2, varscan2
- ZNF474 | c.462C>T p.N154= | Silent (SNP) | VAF 147/307 reads (48%) | catalogued as rs143953702, COSV56947759; called by muse, mutect2, varscan2
- ZNF804A | c.666G>A p.A222= | Silent (SNP) | VAF 211/447 reads (47%) | catalogued as rs779143111, COSV56453703; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73848787 G>A | 5'Flank (SNP) | VAF 30/468 reads (6%) | called by muse, mutect2
- ARMCX4 | c.1038+3408T>C | Intron (SNP) | VAF 441/934 reads (47%) | called by muse, mutect2, varscan2
- C7orf77 | n.186C>T | RNA (SNP) | VAF 59/219 reads (27%) | called by muse, mutect2, varscan2
- DCLK3 | c.-336C>T | 5'UTR (SNP) | VAF 121/355 reads (34%) | catalogued as rs1180863004; called by muse, mutect2, varscan2
- DTNA | c.1094+1750G>T | Intron (SNP) | VAF 118/241 reads (49%) | called by muse, mutect2, varscan2
- MAGEC3 | c.1124-115G>T | Intron (SNP) | VAF 355/711 reads (50%) | called by muse, mutect2, varscan2
- MARCHF1 | c.163-63del | Intron (DEL) | VAF 100/340 reads (29%) | called by mutect2, pindel, varscan2
- MDGA1 | c.2776+66T>C | Intron (SNP) | VAF 181/624 reads (29%) | called by muse, mutect2, varscan2
- SILC1 | n.347C>T | RNA (SNP) | VAF 191/334 reads (57%) | catalogued as rs886898497; called by muse, mutect2, varscan2
- TCF7L2 | c.1442+671C>T | Intron (SNP) | VAF 277/523 reads (53%) | catalogued as COSV53336375, COSV53339511; called by muse, mutect2, varscan2
- VMA21 | chrX:151396907 A>C | 5'Flank (SNP) | VAF 78/664 reads (12%) | called by muse, mutect2, varscan2
